Somatic mutation profile of tumor specimen BA2171D (aliquot aq-BA2171D) from BEATAML1.0 case 2321, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.3 years (26,755 days).
Specimen BA2171D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 451f04ba-d46d-4694-9442-b14d8148555c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2771D (Solid Tissue Normal), aliquot aq-BA2771D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/215472c8-5bfc-43f7-a360-a9455a4256b6

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SYNJ2 | c.531C>A p.C177* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- AC012236.1 | n.313G>T | RNA (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
